CCDI case PBBKUF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/adae120a-74aa-47a0-a75c-62a7cafea069

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myofibroma: ICD-O-3 morphology code: 8824/0; Tissue or organ of origin: Bones of skull and face and associated joints; Age at diagnosis: 3.7 years (1,335 days).

Biospecimens (3 samples)
- Sample 0DB9NU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB9NX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB9O5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
